Somatic mutation profile of tumor specimen 0DUUQ4 from CCDI case PBCLVD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.6 years (1,686 days).
Specimen 0DUUQ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d79d98c-59e3-4ba6-87e4-7f711c8af1ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUUPQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7aca46a0-68ab-4cb3-a179-492c904505f1

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'UTR 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD45 | c.771G>C p.Q257H | Missense Mutation (SNP) | VAF 251/431 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1436599924; called by muse, mutect2, varscan2
- CCDC136 | c.2015G>A p.C672Y | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs751024414, COSV99921990; called by muse, mutect2, varscan2
- HIP1R | c.135del p.V46* | Frame Shift Del (DEL) | VAF 98/240 reads (41%) | catalogued as COSV99458973; called by mutect2, varscan2
- MLXIPL | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs1355050653; called by muse, mutect2
- RNF14 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 182/404 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as rs779355497; called by muse, mutect2, varscan2
- SLC66A1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 147/295 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs574979547, COSV100913221; called by muse, mutect2, varscan2
- BHLHE41 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 166/267 reads (62%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- RNF182 | c.80A>T p.Y27F | Missense Mutation (SNP) | VAF 175/420 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CDYL2 | c.1095G>T p.L365= | Silent (SNP) | VAF 80/97 reads (82%) | catalogued as COSV73653929; called by muse, mutect2, varscan2
- C1orf122 | c.-29G>A | 5'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
